Somatic mutation profile of tumor specimen MMRF_1915_1_BM_CD138pos (aliquot MMRF_1915_1_BM_CD138pos_T1_KBS5U_L07247) from MMRF case MMRF_1915, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 60.4 years (22,051 days).
Specimen MMRF_1915_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 403d84d2-14b0-4707-9875-ca0e84846152.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1915_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1915_1_PB_Whole_C3_KBS5U_L07248; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/669b621f-3879-4f2e-a255-6b353a8ee6d1

The open-access MAF lists 189 somatic variants for this specimen: 82 protein-altering or splice-affecting, 30 silent, 77 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, 3'UTR 47, Silent 30, Intron 15, 5'UTR 6, Nonsense Mutation 5, Splice Site 5, 3'Flank 5, Splice Region 2, 5'Flank 2, RNA 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1622A>C p.E541A (on ENST00000288602 / NM_001374244.1; = p.E501A on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs180177039, CM060875, CM076030, CM150460; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.994-1G>C p.X332_splice | Splice Site (SNP) | VAF 10/67 reads (15%) | hotspot (GDC flag); catalogued as rs587782272, CS002470, CS033842, CS103209, COSV52668116, COSV52746625, COSV52766192; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 9/101 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148924904, CM942135, COSV52663142, COSV52676381; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- TP53 | c.377A>G p.Y126C | Missense Mutation (SNP) | VAF 33/127 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555526335, CM115636, COSV52689293, COSV52760406, COSV52970718; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AC097636.1 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 28/282 reads (10%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV71309642; called by muse, mutect2, varscan2
- ASB4 | c.1180A>G p.R394G | Missense Mutation (SNP) | VAF 37/202 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as rs1257295643; called by muse, mutect2, varscan2
- BCL7A | c.92+2T>G p.X31_splice | Splice Site (SNP) | VAF 17/39 reads (44%) | catalogued as rs200458522; called by muse, mutect2, varscan2
- BNC1 | c.1211G>A p.R404H | Missense Mutation (SNP) | VAF 4/79 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61756516; called by muse, mutect2
- CAPZA3 | c.128T>G p.L43R | Missense Mutation (SNP) | VAF 139/294 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56851538; called by muse, mutect2, varscan2
- CST4 | c.140C>A p.A47D | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1192032312; called by muse, mutect2
- DISP1 | c.1319A>G p.K440R | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV52663920; called by muse, mutect2, varscan2
- FGD1 | c.955A>G p.S319G | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV100910867; called by muse, mutect2, varscan2
- GABRA6 | c.828G>T p.G276= | Splice Region (SNP) | VAF 24/125 reads (19%) | catalogued as COSV50879276; called by muse, mutect2, varscan2
- GABRB2 | c.899C>A p.P300H | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50949466; called by muse, mutect2, varscan2
- HERC4 | c.2669A>T p.K890I (on ENST00000395198 / NM_022079.3; = p.K882I on NM_015601.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/126 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.213); catalogued as rs1191334519; called by muse, mutect2, varscan2
- IGLV7-46 | c.211G>C p.D71H | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs1415265529; called by muse, mutect2, varscan2
- LAMB2 | c.76G>A p.V26M | Missense Mutation (SNP) | VAF 161/323 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.119); catalogued as rs1420222075; called by muse, varscan2
- LONRF2 | c.1219G>A p.V407M | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs562655594, COSV101111037, COSV66539431; called by muse, mutect2, varscan2
- ODF3L2 | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.64); catalogued as rs1350991626; called by muse, mutect2
- PPP1R3A | c.1629G>T p.R543S | Missense Mutation (SNP) | VAF 34/342 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.324); catalogued as COSV99491863; called by muse, mutect2, varscan2
- PPP2R5B | c.1276A>C p.K426Q | Missense Mutation (SNP) | VAF 57/133 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs1565107190; called by muse, mutect2, varscan2
- PRPF8 | c.4780T>C p.C1594R | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV100517817; called by muse, mutect2, varscan2
- PTCHD1 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.029); catalogued as COSV65062395; called by muse, mutect2, varscan2
- PTCHD4 | c.1213T>C p.F405L | Missense Mutation (SNP) | VAF 88/214 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as rs1324179636; called by muse, mutect2
- SH3RF3 | c.1668T>A p.S556R | Missense Mutation (SNP) | VAF 19/176 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1553520761, COSV58692821; called by muse, mutect2, varscan2
- SLC5A1 | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as COSV56689925; called by muse, mutect2
- SPSB3 | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.714); catalogued as rs754518685, COSV51905902; called by muse, mutect2, varscan2
- SPTBN4 | c.5674C>T p.R1892W | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs371693029; called by muse, mutect2, varscan2
- ADGRG2 | c.596C>A p.A199E (on ENST00000379869 / NM_001079858.3; = p.A196E on NM_005756.4) | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- ADPRHL1 | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP7A | c.2053C>T p.Q685* | Nonsense Mutation (SNP) | VAF 81/225 reads (36%) | called by muse, mutect2, varscan2
- ATPSCKMT | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.062); called by muse, mutect2
- CD34 | c.695T>A p.L232H | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.951); called by muse, mutect2
- CDKL1 | c.15T>G p.Y5* | Nonsense Mutation (SNP) | VAF 44/213 reads (21%) | called by muse, mutect2, varscan2
- CFAP58 | c.2195C>A p.T732N | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.096); called by muse, mutect2
- CHRNA3 | c.626T>C p.I209T | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- CXADR | c.896A>T p.H299L | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- DIP2A | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DLGAP1 | c.1405A>T p.S469C | Missense Mutation (SNP) | VAF 79/228 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- DMTF1 | c.232+1G>C p.X78_splice | Splice Site (SNP) | VAF 61/128 reads (48%) | called by muse, mutect2, varscan2
- DPP4 | c.424C>A p.L142M | Missense Mutation (SNP) | VAF 156/342 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- EHF | c.185T>C p.L62P | Missense Mutation (SNP) | VAF 57/133 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ERF | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ERN1 | c.992_993del p.E331Vfs*12 | Frame Shift Del (DEL) | VAF 16/58 reads (28%) | called by mutect2, varscan2
- EVX2 | c.1320C>A p.S440R | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.129); called by muse, mutect2
- FLG2 | c.3958G>T p.D1320Y | Missense Mutation (SNP) | VAF 7/184 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2
- GPR119 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 79/195 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPR12 | c.463A>T p.T155S | Missense Mutation (SNP) | VAF 92/188 reads (49%) | SIFT tolerated (0.6); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- HGF | c.829C>G p.H277D | Missense Mutation (SNP) | VAF 6/107 reads (6%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2
- HK3 | c.1068G>A p.E356= | Splice Region (SNP) | VAF 92/567 reads (16%) | called by muse, mutect2, varscan2
- IARS1 | c.2473A>G p.M825V | Missense Mutation (SNP) | VAF 11/182 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); called by muse, mutect2
- IGLV5-45 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 74/178 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.299); called by muse, varscan2
- IRS4 | c.3518A>G p.E1173G | Missense Mutation (SNP) | VAF 146/337 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- KCNA4 | c.858G>C p.E286D | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KCNH1 | c.2858A>G p.E953G (on ENST00000271751 / NM_172362.3; = p.E926G on NM_002238.4) | Missense Mutation (SNP) | VAF 33/150 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- KHK | c.92+1G>C p.X31_splice | Splice Site (SNP) | VAF 11/156 reads (7%) | called by muse, mutect2
- KLHL15 | c.705+1G>A p.X235_splice | Splice Site (SNP) | VAF 5/49 reads (10%) | called by muse, mutect2, varscan2
- LNX1 | c.626G>A p.R209Q (on ENST00000263925 / NM_001126328.3; = p.R113Q on NM_032622.2) | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.011); called by muse, mutect2
- MUC22 | c.779C>G p.A260G | Missense Mutation (SNP) | VAF 21/402 reads (5%) | SIFT deleterious, low confidence (0.04); called by muse, mutect2
- MYO7B | c.1598C>A p.A533D | Missense Mutation (SNP) | VAF 35/163 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- OTUD6A | c.262C>A p.P88T | Missense Mutation (SNP) | VAF 80/189 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- PICK1 | c.586G>A p.V196M | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- PPP1R15A | c.79_99del p.G27_W33del | In Frame Del (DEL) | VAF 47/117 reads (40%) | called by mutect2, pindel, varscan2
- RCHY1 | c.406T>C p.C136R | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RGR | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- ROBO2 | c.1349G>T p.S450I | Missense Mutation (SNP) | VAF 82/184 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- RP1 | c.3457G>C p.A1153P | Missense Mutation (SNP) | VAF 110/254 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- RYR2 | c.3848T>A p.L1283* | Nonsense Mutation (SNP) | VAF 24/165 reads (15%) | called by muse, mutect2, varscan2
- SGK1 | c.290A>G p.D97G | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- SLCO1B3 | c.1693C>T p.P565S | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); called by muse, mutect2
- SOX17 | c.1089T>G p.F363L | Missense Mutation (SNP) | VAF 93/216 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- THSD7A | c.1999G>C p.A667P | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- TIGD5 | c.1619G>T p.G540V | Missense Mutation (SNP) | VAF 45/89 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TMEM179 | c.598C>A p.R200S | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- TMEM53 | c.671T>A p.L224Q | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TRIM59 | c.403C>T p.Q135* | Nonsense Mutation (SNP) | VAF 10/160 reads (6%) | called by muse, mutect2
- TRIML2 | c.178G>C p.E60Q | Missense Mutation (SNP) | VAF 23/212 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- UGGT2 | c.3029C>G p.P1010R | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- UNC5D | c.1769T>C p.L590P | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.018); called by muse, varscan2
- ZDHHC6 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0.005); called by muse, mutect2
- ZKSCAN5 | c.1786C>T p.Q596* | Nonsense Mutation (SNP) | VAF 31/207 reads (15%) | called by muse, mutect2, varscan2
- ZXDA | c.2189C>A p.T730K | Missense Mutation (SNP) | VAF 52/323 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ADGRB3 | c.1653C>T p.L551= | Silent (SNP) | VAF 19/105 reads (18%) | called by muse, mutect2, varscan2
- ANK1 | c.3192G>T p.V1064= | Silent (SNP) | VAF 11/155 reads (7%) | called by muse, mutect2
- C2orf78 | c.1266C>T p.S422= | Silent (SNP) | VAF 39/164 reads (24%) | catalogued as COSV68517758; called by muse, mutect2, varscan2
- CBX1 | c.222A>G p.A74= | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as rs933641058; called by muse, mutect2, varscan2
- CEP192 | c.1677G>T p.L559= | Silent (SNP) | VAF 16/193 reads (8%) | called by muse, mutect2
- CEP78 | c.1167C>T p.F389= (on ENST00000424347 / NM_001349840.2; = p.F390= on NM_032171.3) | Silent (SNP) | VAF 42/185 reads (23%) | called by muse, mutect2, varscan2
- CLEC17A | c.546C>T p.F182= | Silent (SNP) | VAF 6/108 reads (6%) | catalogued as rs1187302697, COSV60429254; called by muse, mutect2
- EGFR | c.3576T>A p.A1192= | Silent (SNP) | VAF 25/518 reads (5%) | called by muse, mutect2
- ELANE | c.240G>A p.V80= | Silent (SNP) | VAF 10/176 reads (6%) | called by muse, mutect2
- ELANE | c.241C>A p.R81= | Silent (SNP) | VAF 10/176 reads (6%) | catalogued as rs1131691914, CD135422, COSV55048660; called by muse, mutect2
- FGA | c.1632T>C p.T544= | Silent (SNP) | VAF 39/188 reads (21%) | catalogued as CD091544; called by muse, mutect2, varscan2
- GPR139 | c.42G>T p.L14= | Silent (SNP) | VAF 9/39 reads (23%) | called by muse, mutect2
- IGLV5-45 | c.231G>A p.K77= | Silent (SNP) | VAF 66/160 reads (41%) | catalogued as rs370576104; called by muse, varscan2
- KNDC1 | c.2469C>T p.H823= | Silent (SNP) | VAF 31/70 reads (44%) | catalogued as rs560440547; called by muse, mutect2, varscan2
- MAP10 | c.1014C>G p.L338= | Silent (SNP) | VAF 13/126 reads (10%) | called by muse, mutect2, varscan2
- MRC2 | c.606C>T p.T202= | Silent (SNP) | VAF 5/83 reads (6%) | catalogued as rs1207151155; called by muse, mutect2
- NOTCH3 | c.6315G>T p.L2105= | Silent (SNP) | VAF 35/68 reads (51%) | called by muse, mutect2, varscan2
- OR51Q1 | c.63A>G p.G21= | Silent (SNP) | VAF 201/397 reads (51%) | called by muse, mutect2, varscan2
- PANX2 | c.1383G>A p.K461= | Silent (SNP) | VAF 16/39 reads (41%) | called by muse, mutect2, varscan2
- PDE6A | c.2316T>A p.L772= | Silent (SNP) | VAF 20/106 reads (19%) | catalogued as rs776326612; called by muse, mutect2, varscan2
- PHGDH | c.921G>A p.V307= | Silent (SNP) | VAF 34/128 reads (27%) | called by muse, mutect2, varscan2
- PPP1R21 | c.2094A>G p.A698= (on ENST00000294952 / NM_001135629.3; = p.A687= on NM_152994.5) | Silent (SNP) | VAF 21/112 reads (19%) | called by muse, mutect2, varscan2
- PRRC2C | c.8208G>A p.Q2736= (on ENST00000367742; = p.Q2734= on NM_015172.4) | Silent (SNP) | VAF 28/147 reads (19%) | catalogued as COSV58914310; called by muse, mutect2, varscan2
- RAB33A | c.516C>A p.A172= | Silent (SNP) | VAF 42/240 reads (18%) | called by muse, mutect2, varscan2
- RAG1 | c.2169T>A p.A723= | Silent (SNP) | VAF 11/105 reads (10%) | catalogued as rs747972423; called by muse, mutect2, varscan2
- RIMS1 | c.1659C>T p.S553= | Silent (SNP) | VAF 43/90 reads (48%) | called by muse, varscan2
- SLCO1C1 | c.2121C>T p.G707= | Silent (SNP) | VAF 16/562 reads (3%) | called by muse, mutect2
- SSMEM1 | c.282C>G p.A94= | Silent (SNP) | VAF 28/178 reads (16%) | called by muse, mutect2, varscan2
- STIP1 | c.1062C>T p.Y354= | Silent (SNP) | VAF 23/106 reads (22%) | catalogued as rs775308727; called by muse, mutect2, varscan2
- TMEM104 | c.1227G>T p.V409= | Silent (SNP) | VAF 8/122 reads (7%) | called by muse, mutect2
- ABL1 | c.*1706G>A | 3'UTR (SNP) | VAF 130/283 reads (46%) | called by muse, mutect2, varscan2
- ALPI | c.*75C>T | 3'UTR (SNP) | VAF 14/88 reads (16%) | catalogued as rs77906818; called by mutect2, varscan2
- B3GALT5-AS1 | n.778G>C | RNA (SNP) | VAF 23/349 reads (7%) | called by muse, mutect2
- BEND4 | c.*5782C>T | 3'UTR (SNP) | VAF 59/122 reads (48%) | catalogued as rs979196104; called by muse, mutect2, varscan2
- BMX | c.*338C>T | 3'UTR (SNP) | VAF 8/79 reads (10%) | called by muse, mutect2
- C10orf67 | c.206+554A>G | Intron (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
- CAMKMT | c.377-72655A>G | Intron (SNP) | VAF 104/223 reads (47%) | catalogued as rs1482965641; called by muse, mutect2, varscan2
- CCDC90B | c.*1069C>T | 3'UTR (SNP) | VAF 130/218 reads (60%) | catalogued as rs145299725; called by muse, mutect2, varscan2
- CD93 | c.*4344G>T | 3'UTR (SNP) | VAF 6/85 reads (7%) | called by muse, mutect2
- CHTOP | c.404-349G>A | Intron (SNP) | VAF 5/51 reads (10%) | called by muse, mutect2, varscan2
- CLCN5 | c.17-32532C>A | Intron (SNP) | VAF 48/111 reads (43%) | called by muse, mutect2, varscan2
- CYBRD1 | c.*744A>G | 3'UTR (SNP) | VAF 41/82 reads (50%) | called by muse, mutect2, varscan2
- DAND5 | c.*123G>A | 3'UTR (SNP) | VAF 3/39 reads (8%) | catalogued as rs1325428382; called by muse, mutect2
- DEFB118 | c.*316T>C | 3'UTR (SNP) | VAF 11/73 reads (15%) | called by muse, mutect2, varscan2
- DLX3 | c.*1293G>C | 3'UTR (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- ERMAP | c.86-32T>G | Intron (SNP) | VAF 14/280 reads (5%) | called by muse, mutect2
- FAM124B | c.-122A>T | 5'UTR (SNP) | VAF 44/98 reads (45%) | called by muse, mutect2, varscan2
- FAM124B | c.-123T>A | 5'UTR (SNP) | VAF 43/97 reads (44%) | called by muse, mutect2, varscan2
- FAT3 | c.*3010A>T | 3'UTR (SNP) | VAF 9/114 reads (8%) | called by muse, mutect2
- GABRA2 | c.187+17688A>T | Intron (SNP) | VAF 71/141 reads (50%) | called by muse, mutect2, varscan2
- GASK1B | c.910+1151G>C | Intron (SNP) | VAF 16/110 reads (15%) | called by muse, mutect2, varscan2
- GLRB | c.*594A>G | 3'UTR (SNP) | VAF 11/113 reads (10%) | called by muse, mutect2
- GPR78 | c.*275G>T | 3'UTR (SNP) | VAF 35/170 reads (21%) | called by muse, mutect2, varscan2
- GRAMD1B | c.*4600C>G | 3'UTR (SNP) | VAF 8/146 reads (5%) | called by muse, mutect2
- GREB1 | c.*1685G>C | 3'UTR (SNP) | VAF 5/26 reads (19%) | called by muse, mutect2
- GRIK4 | chr11:120988132 T>G | 3'Flank (SNP) | VAF 8/81 reads (10%) | called by muse, mutect2, varscan2
- HCN1 | c.*2411A>C | 3'UTR (SNP) | VAF 13/103 reads (13%) | called by muse, mutect2, varscan2
- HS6ST2 | c.*477T>C | 3'UTR (SNP) | VAF 9/158 reads (6%) | called by muse, mutect2
- IDO2 | chr8:40015685 A>T | 3'Flank (SNP) | VAF 18/42 reads (43%) | called by muse, mutect2
- IFRD1 | c.409+63A>G | Intron (SNP) | VAF 24/271 reads (9%) | catalogued as rs1000480162; called by muse, mutect2
- IL22RA2 | c.*1661G>A | 3'UTR (SNP) | VAF 45/97 reads (46%) | called by muse, mutect2, varscan2
- ITPR1 | c.*1160A>T | 3'UTR (SNP) | VAF 41/82 reads (50%) | called by muse, mutect2, varscan2
- KAT7 | c.*1410T>G | 3'UTR (SNP) | VAF 14/136 reads (10%) | called by muse, mutect2
- KSR1 | c.*2113G>T | 3'UTR (SNP) | VAF 13/104 reads (13%) | called by muse, mutect2, varscan2
- LIN52 | c.-161G>A | 5'UTR (SNP) | VAF 28/114 reads (25%) | called by mutect2, varscan2
- MAP3K2 | c.*6903C>T | 3'UTR (SNP) | VAF 54/128 reads (42%) | called by muse, mutect2, varscan2
- MEGF6 | c.-183C>T | 5'UTR (SNP) | VAF 4/21 reads (19%) | called by muse, mutect2, varscan2
- MIR5195 | n.75G>A | RNA (SNP) | VAF 45/45 reads (100%) | called by muse, mutect2, varscan2
- MUC19 | chr12:40421247 A>C | 3'Flank (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- MYADML2 | c.*99G>A | 3'UTR (SNP) | VAF 39/97 reads (40%) | catalogued as rs1428997149; called by muse, mutect2, varscan2
- NAALAD2 | chr11:90134621 A>G | 5'Flank (SNP) | VAF 7/128 reads (5%) | called by muse, mutect2
- NFATC2IP | c.*2160T>C | 3'UTR (SNP) | VAF 4/11 reads (36%) | called by muse, mutect2
- NKIRAS1 | chr3:23891060 T>C | 3'Flank (SNP) | VAF 10/84 reads (12%) | called by muse, mutect2, varscan2
- NPHP1 | c.*228G>T | 3'UTR (SNP) | VAF 18/42 reads (43%) | catalogued as rs573818571; called by muse, mutect2, varscan2
- PAX5 | c.-65A>G | 5'UTR (SNP) | VAF 10/26 reads (38%) | called by muse, mutect2
- PHLDB1 | c.2737-796G>C | Intron (SNP) | VAF 31/201 reads (15%) | called by mutect2, varscan2
- PHLDB2 | c.1719+476T>C | Intron (SNP) | VAF 38/68 reads (56%) | called by muse, mutect2, varscan2
- PLD5 | c.*182A>T | 3'UTR (SNP) | VAF 34/121 reads (28%) | called by muse, mutect2, varscan2
- PLEKHG4B | c.*2290T>A | 3'UTR (SNP) | VAF 14/49 reads (29%) | called by muse, mutect2, varscan2
- PLOD3 | c.1683+88T>G | Intron (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2, varscan2
- PLPPR5 | c.*5G>A | 3'UTR (SNP) | VAF 109/415 reads (26%) | catalogued as rs11585908; called by muse, mutect2, varscan2
- PRRG1 | c.*3108T>A | 3'UTR (SNP) | VAF 10/198 reads (5%) | called by muse, mutect2
- RAD52 | c.*315_*331del | 3'UTR (DEL) | VAF 5/57 reads (9%) | called by pindel, varscan2*
- RBM25 | c.*1463G>A | 3'UTR (SNP) | VAF 12/168 reads (7%) | called by muse, mutect2
- RPL7P3 | chr20:62570446 C>T | 5'Flank (SNP) | VAF 48/89 reads (54%) | catalogued as rs1555904332; called by muse, mutect2, varscan2
- SAT1 | c.202+204T>C | Intron (SNP) | VAF 34/96 reads (35%) | called by muse, mutect2, varscan2
- SERP1 | c.*133G>C | 3'UTR (SNP) | VAF 51/245 reads (21%) | called by muse, mutect2, varscan2
- SFXN3 | c.*1234G>T | 3'UTR (SNP) | VAF 4/64 reads (6%) | called by muse, mutect2
- SIK2 | c.*1309T>G | 3'UTR (SNP) | VAF 8/191 reads (4%) | called by muse, mutect2
- SNX10 | c.*27G>A | 3'UTR (SNP) | VAF 14/360 reads (4%) | called by muse, mutect2
- TMCO5A | c.627+864A>G | Intron (SNP) | VAF 10/91 reads (11%) | called by muse, mutect2, varscan2
- TMEM184A | c.*181C>T | 3'UTR (SNP) | VAF 13/35 reads (37%) | called by muse, mutect2, varscan2
- TMEM211 | chr22:24935077 T>C | 3'Flank (SNP) | VAF 12/35 reads (34%) | called by muse, mutect2, varscan2
- TMEM80 | c.*304_*316del | 3'UTR (DEL) | VAF 51/118 reads (43%) | called by mutect2, pindel, varscan2
- TOR1B | c.*1280G>T | 3'UTR (SNP) | VAF 5/72 reads (7%) | called by muse, mutect2
- TRIM24 | c.*3402T>A | 3'UTR (SNP) | VAF 13/40 reads (33%) | called by muse, mutect2, varscan2
- TRIM40 | c.-235C>T | 5'UTR (SNP) | VAF 55/137 reads (40%) | catalogued as rs1268400481; called by muse, mutect2, varscan2
- TUBGCP5 | c.*182A>G | 3'UTR (SNP) | VAF 15/79 reads (19%) | called by muse, mutect2, varscan2
- TXNL1 | c.*3728T>A | 3'UTR (SNP) | VAF 68/119 reads (57%) | called by muse, mutect2, varscan2
- UGT1A6 | c.862-12079G>A | Intron (SNP) | VAF 130/263 reads (49%) | catalogued as rs767638744, COSV100529352; called by muse, mutect2, varscan2
- UQCRB | c.*3018T>C | 3'UTR (SNP) | VAF 8/106 reads (8%) | called by muse, mutect2
- VSIG1 | c.*1483T>C | 3'UTR (SNP) | VAF 13/223 reads (6%) | called by muse, mutect2
- WDTC1 | c.*861T>A | 3'UTR (SNP) | VAF 103/168 reads (61%) | called by muse, mutect2, varscan2
- WNT7B | c.71+4195C>T | Intron (SNP) | VAF 11/37 reads (30%) | catalogued as rs1417935787; called by muse, mutect2, varscan2
- ZNF135 | c.*326C>G | 3'UTR (SNP) | VAF 16/209 reads (8%) | called by muse, mutect2
- ZNF474 | c.*102T>C | 3'UTR (SNP) | VAF 64/402 reads (16%) | called by muse, mutect2, varscan2
- ZNF557 | c.*142T>G | 3'UTR (SNP) | VAF 7/31 reads (23%) | called by muse, mutect2, varscan2
